Surgical pathology report (de-identified scan), TCGA case TCGA-HD-7753, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-HD-7753-01A (Primary Tumor).

[page 1 of 2]
Surg Path Final Report

* Final Report *

Result Type:
Result Date:
Result Status:
Result Title:
Verified By:
Encounter info:

Final Report

Final Diagnosis (Verified)

Pharyngeal wall, Resection:

Squamous cell carcinoma, moderately differentiated.

Lymphovascular and perineural invasion are not identified.

Left lateral margin is positive for tumor. Tumor is separated from the right lateral margin by few collagen bundles.

Superior, inferior, and deep margins are negative for tumor in the planes of section examined.

This report was dictated by [REDACTED] under the supervision of [REDACTED]

Signature Line

Frozen Section Diagnosis (Verified)

Pharyngeal wall, excision

Gross: Soft tissue fragment measuring 5.0 x 4.5 x 1.8 cm.

Printed by:
Printed on:

Page 1 of 2
(Continued)

[page 2 of 2]
Surg Path Final Report

* Final Report *

Inked as follows:

- Superior → red
- Inferior → orange
- Deep → black
- Left lateral → blue
- Right lateral → green

Microscopic

Squamous cell carcinoma present at left lateral margin (blue).

Clinical Information (Verified)

Oropharyngeal wall squamous cell carcinoma.

Gross Description (Verified)

"A," Received after frozen section is a soft tissue fragment which measures 5 x 4.5 x 1.8 cm at frozen section. The margins have been previously inked as follows. Superior red, inferior orange, deep black, left lateral blue, right lateral green. There is a 2.3 x 1.7 cm ulcerated mass on the mucosa. The mass grossly appears to abut the left lateral margin, comes to within 0.5 cm of the right lateral margin, comes to within 0.3 cm of the deep margin, and to within 1 cm of the inferior margin. The superior margin is in the container in a tea bag and will be submitted. A portion of the specimen has been submitted for frozen section in "FSA". "A1," superior margin; "A2," section of inferior margin to include mass; "A3," mass to include left lateral margin and deep margin; "A4," mass to include right lateral margin and deep margin.

Signature Line

Completed Action List:

Printed by:
Printed on:

Page 2 of 2
(End of Report)

Source: NCI Genomic Data Commons file 097ba8b1-a6c3-44e8-a3e4-07d891f4f10c (TCGA-HD-7753.02DEBE2A-B6ED-4DE8-B387-D781842C3A84.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).